MMRF case MMRF_1740 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0b255f54-4366-40cf-a877-2cbf5aafd0f4

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 83 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 84.0 years (30,671 days); ISS stage: II; Days to last known disease status: 989 days (2.7 years); Days to last follow up: 989 days (2.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 715 days (2.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 989.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 3): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 63.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 5.45 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 33 g/L; Total Protein 7.6 g/dL; Glucose 11.7 mmol/L; C-Reactive Protein 3.7 mg/dL.
- Day 84 (ECOG 2): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 9.13 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 1.85 mmol/L; Albumin 32 g/L; Total Protein 6.7 g/dL; Glucose 8.2 mmol/L.
- Day 191 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.41 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.03 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 9.41 mmol/L.
- Day 275 (ECOG 2): M Protein 0 g/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 3.11 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 5.21 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 7.37 mmol/L.
- Day 338 (ECOG 2): M Protein 0 g/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 3.55 g/L; Immunoglobulin M 0.62 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 7.7 g/dL; Glucose 7.32 mmol/L.
- Day 456 (ECOG 2): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 2.45 g/L; Immunoglobulin M 0.94 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 6.9 g/dL; Glucose 5.94 mmol/L.
- Day 523: M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.97 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 7.81 mmol/L.
- Day 621 (ECOG 2): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.66 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 7.15 mmol/L.
- Day 712 (ECOG 3): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 79.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 22.7 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 8.2 g/dL; Glucose 8.97 mmol/L.
- Day 806 (ECOG 2): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 84.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 23.3 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 8.4 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day 0: Weight: 71 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1740_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1740_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
